Somatic mutation profile of tumor specimen TCGA-CN-A499-01A (aliquot TCGA-CN-A499-01A-11D-A24D-08) from TCGA case TCGA-CN-A499, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.2 years (21,971 days).
Specimen TCGA-CN-A499-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0482b688-2e5a-44b5-845a-698f1ff42034.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A499-10A (Blood Derived Normal), aliquot TCGA-CN-A499-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/710a904a-a594-4089-af05-c32a12ce520d

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY9 | c.3788G>A p.R1263H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.08); catalogued as rs773282474, COSV53572362; called by muse, mutect2, varscan2
- ALKBH5 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101213278, COSV101213304; called by muse, mutect2, varscan2
- BCORL1 | c.5083G>A p.D1695N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV99499951; called by muse, mutect2, varscan2
- CDH10 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs770163052, COSV100051956; called by muse, mutect2
- CEACAM6 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs781867074, COSV99555614; called by muse, mutect2
- CPSF7 | c.715C>T p.P239S (on ENST00000394888 / NM_001136040.4; = p.P282S on NM_024811.4) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.108); catalogued as COSV100467409; called by muse, mutect2, varscan2
- DGKG | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99402702, COSV99403649; called by muse, mutect2, varscan2
- GPR155 | c.881G>A p.C294Y | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99789990; called by muse, mutect2
- GRM3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862005; called by muse, mutect2, varscan2
- KDM2A | c.3164C>T p.T1055M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58191105; called by muse, mutect2, varscan2
- MYH2 | c.5540G>A p.R1847H | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs748605415, COSV55434665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR1C1 | c.334A>G p.S112G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.936); catalogued as COSV101376242; called by muse, mutect2, varscan2
- OR8H3 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs540879053, COSV57909902; called by muse, mutect2, varscan2
- OTX1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99246383; called by muse, mutect2, varscan2
- PCDHAC2 | c.2344C>T p.R782* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as rs1380719565, COSV53850303, COSV53850589; called by muse, mutect2, varscan2
- PKHD1 | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs191201723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRD | c.1862C>A p.P621Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV100645325, COSV61933716; called by muse, mutect2
- RANBP2 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs549497956, COSV51697831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBBP8 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100507480, COSV99045597; called by muse, mutect2, varscan2
- RHCE | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs147526117, COSV53799581; called by muse, mutect2, varscan2
- SMR3A | c.269A>T p.Q90L | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99895722; called by muse, mutect2, varscan2
- STAC | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs557489939, COSV99830233; called by muse, mutect2, varscan2
- UBR3 | c.5215G>A p.E1739K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV55849543, COSV99774339; called by muse, mutect2
- ZNF354A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV100234534; called by mutect2, varscan2
- KRT15 | c.857_859del p.A286del | In Frame Del (DEL) | VAF 72/257 reads (28%) | called by mutect2, pindel, varscan2
- PLA2G4F | c.837_839del p.S280del | In Frame Del (DEL) | VAF 9/26 reads (35%) | called by pindel, varscan2
- PTEN | c.155dup p.D52Efs*11 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- ABAT | c.6C>T p.A2= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs987724126, COSV99190970; called by muse, mutect2
- ASTN2 | c.1434C>T p.F478= (on ENST00000313400 / NM_001365069.1; = p.F427= on NM_014010.5) | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs201483760, COSV57798041; called by muse, mutect2
- CEP68 | c.1860A>G p.K620= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as COSV99561018; called by muse, mutect2, varscan2
- DNAH5 | c.11193C>A p.V3731= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99451036; called by muse, mutect2, varscan2
- EFCAB13 | c.1176A>G p.K392= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100516663; called by muse, mutect2, varscan2
- IFNL3 | c.87G>C p.G29= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV101308020; called by muse, mutect2, varscan2
- KIAA0408 | c.612A>G p.P204= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100846963; called by muse, mutect2
- NGDN | c.150C>T p.L50= | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV101238892; called by muse, mutect2, varscan2
- OPN1MW | c.801G>A p.T267= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs1162383918; called by muse, mutect2, varscan2
- KCNC2 | c.*765G>A | 3'UTR (SNP) | VAF 14/41 reads (34%) | catalogued as rs755983385, COSV100129118; called by muse, mutect2, varscan2
